TCGA case TCGA-LK-A4O6 — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d940e476-fb0a-4cc3-8ab5-691156e7c09b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Dead; Days to death: 448 days (1.2 years).

Diagnoses (1)
1. Mesothelioma, biphasic, malignant: ICD-O-3 morphology code: 9053/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 66.9 years (24,449 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 448 days (1.2 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 49 days; Disease response: With Tumor.
- Days to follow up: 448 days (1.2 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-LK-A4O6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 370 mg.
  Slide TCGA-LK-A4O6-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-LK-A4O6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-LK-A4O6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Biphasic mesothelioma.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 448 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 448 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 448 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-LK-A4O6-01A-11D-A34B-01): tumor purity 0.31, ploidy 1.92, whole-genome doublings 0.
